Somatic mutation profile of tumor specimen TARGET-10-PAPDDA-09A (aliquot TARGET-10-PAPDDA-09A-01D) from TARGET case TARGET-10-PAPDDA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,685 days).
Specimen TARGET-10-PAPDDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e61262a-430b-43c8-ab03-d56339a3162e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDDA-10A (Blood Derived Normal), aliquot TARGET-10-PAPDDA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c889dfc-e790-404f-a00e-80bbeeecbb67

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Silent 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs397507544, CM044932, COSV61005111; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRIK4 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.947); catalogued as rs765839305; called by muse, mutect2, varscan2
- IL12RB2 | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.598); catalogued as rs1217246565; called by muse, mutect2, varscan2
- KDM6B | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779500605; called by muse, mutect2, varscan2
- KIAA1217 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764141082; called by muse, mutect2, varscan2
- TCEAL6 | c.357C>G p.D119E | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.865); catalogued as COSV101036025; called by muse, mutect2, varscan2
- TIMM44 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs766115379; called by muse, mutect2, varscan2
- WLS | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202076524; called by muse, mutect2, varscan2
- ARHGAP23 | c.1216T>C p.S406P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ASXL1 | c.1849dup p.I617Nfs*2 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM81A | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXND1 | c.881_882delinsCCGGGGC p.Q294Pfs*169 | Frame Shift Ins (INS) | VAF 16/22 reads (73%) | called by pindel, varscan2*
- OTOG | c.7050C>T p.Y2350= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs559006203; called by muse, mutect2, varscan2
- CAPN3 | c.1782+677G>A | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- SEZ6 | c.*209C>T | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
